Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7060, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7060-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right upper pole renal mass solid.

Specimens Submitted:

1: SP: Kidney, right; partial nephrectomy (fs)

2: SP: Right kidney, deep surgical margin; excision

DIAGNOSIS:

1. SP: Kidney, right; partial nephrectomy (fs):

Tumor Type:

Renal cell carcinoma - Papillary type

Type 2

Tumor Size:

Greatest diameter is 3.4 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal compression related changes.

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: Right kidney, deep surgical margin; excision:

Benign unremarkable renal parenchyma, confirmed by a PAS stain.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	PAS	

Gross Description:

1). The specimen is received fresh and is labeled "Right renal tumor stitch marks deep surgical margin". It consists of a 4.0 x 3.5 x 2.1 cm wedge shaped portion of kidney with a suture marking the deep margin. There is a portion of fat attached to the superior surface of the cortex. The margin is inked black and the specimen is serially sectioned to reveal a solid green mass measuring 3.4 x 3.0 x 2.5 cm. The clearance from the resection margin is 0.7 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS. Photographs are taken.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

2). The specimen is received in formalin, labeled "Deep surgical margin of right kidney" and consists of a 1.6 x 1.0 x 0.6 cm fragment of tan soft tissue, consistent with kidney tissue. Bisected and entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Kidney, right; partial nephrectomy (fs)

Block	Sect. Site	PCs
1	FSC	1
2	M	2
5	T	5

Part 2: SP: Right kidney, deep surgical margin; excision

Block	Sect. Site	PCs
1	U	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: RIGHT RENAL TUMOR (FS): RENAL CORTICAL NEOPLASM; AREA DESIGNATED BY STITCH IS NEGATIVE FOR TUMOR
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 825fde4e-8d07-4289-8052-bd638d6c2471 (TCGA-BQ-7060.0CCBB12B-90C4-4DE7-B747-12AC43ABF7D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).